Somatic mutation profile of tumor specimen TCGA-ED-A66Y-01A (aliquot TCGA-ED-A66Y-01A-11D-A30V-10) from TCGA case TCGA-ED-A66Y, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 51.5 years (18,797 days).
Specimen TCGA-ED-A66Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef50a36d-4611-4f30-82d6-8234ed1f27bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A66Y-10A (Blood Derived Normal), aliquot TCGA-ED-A66Y-10A-01D-A30V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bd402e1-732d-4f5c-a966-e765f95cac52

The open-access MAF lists 92 somatic variants for this specimen: 78 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 12, Nonsense Mutation 8, Splice Site 5, In Frame Del 2, Intron 1, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1032G>A p.A344= | Silent (SNP) | VAF 40/43 reads (93%) | catalogued as rs121918491, CS941488, COSV60650195; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1216-1G>A p.X406_splice | Splice Site (SNP) | VAF 50/57 reads (88%) | hotspot (GDC flag); catalogued as rs587778831, CS971888, COSV57295479, COSV57298451, COSV57332521; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3429+2T>A p.X1143_splice (on ENST00000404938 / NM_001163941.2; = p.X698_splice on NM_178559.6) | Splice Site (SNP) | VAF 37/72 reads (51%) | catalogued as COSV51712174; called by muse, mutect2
- ACTL7A | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV61776879; called by muse, mutect2, varscan2
- ADCY5 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as COSV71901461; called by mutect2, varscan2
- ANKRD7 | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 213/482 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV54556409, COSV99501122; called by muse, mutect2, varscan2
- ARHGAP31 | c.4016C>A p.S1339* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV51793582, COSV51794565; called by muse, mutect2, varscan2
- ARPC2 | c.761A>G p.H254R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55285241; called by muse, mutect2, varscan2
- ASAH1 | c.504dup p.G169Rfs*21 | Frame Shift Ins (INS) | VAF 17/48 reads (35%) | catalogued as rs768342020; called by mutect2, pindel, varscan2
- CCNC | c.98C>A p.S33* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100412603, COSV58335002; called by muse, mutect2
- CD6 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as rs766424297, COSV57839668; called by muse, mutect2, varscan2
- CEP104 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs963375935, COSV65517973; called by muse, mutect2, varscan2
- CHD3 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57876508; called by muse, mutect2, varscan2
- CHST3 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1272861569, COSV64151183; called by muse, mutect2, varscan2
- CNGA2 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs755787323, COSV61703700, COSV61705041; called by muse, mutect2, varscan2
- COPS4 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV52315680; called by muse, mutect2, varscan2
- CPAMD8 | c.1616G>A p.G539D (on ENST00000651564; = p.G492D on NM_015692.5) | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764946021, COSV52235460; called by muse, mutect2
- CTNNBL1 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 65/142 reads (46%) | catalogued as COSV100799356, COSV63745348; called by muse, mutect2, varscan2
- DNAH1 | c.7762G>C p.G2588R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101325721; called by muse, mutect2, varscan2
- DNAH8 | c.6324C>A p.N2108K | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV59455195; called by muse, mutect2, varscan2
- DONSON | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV51678126; called by muse, mutect2, varscan2
- ELAVL3 | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV63646403; called by muse, mutect2, varscan2
- EPB41L3 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as COSV59451046, COSV59457283; called by muse, mutect2, varscan2
- FBXL7 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.676); catalogued as rs1038279605, COSV61647765; called by muse, mutect2, varscan2
- GPHN | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as rs530173903, COSV59480870; called by muse, mutect2, varscan2
- GRAMD4 | c.283+1G>C p.X95_splice | Splice Site (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100730642, COSV63030847; called by muse, mutect2
- GUCA2B | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 79/114 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV65368173; called by muse, mutect2, varscan2
- HEMK1 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV51750796; called by muse, mutect2, varscan2
- HSPH1 | c.1817T>G p.L606* | Nonsense Mutation (SNP) | VAF 50/101 reads (50%) | catalogued as COSV60711949; called by muse, mutect2, varscan2
- IL4 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs772721636, COSV51502893, COSV51503198; called by muse, mutect2, varscan2
- KCNT2 | c.2543T>G p.M848R | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54086163; called by muse, mutect2, varscan2
- KIAA1586 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV66056853; called by muse, mutect2, varscan2
- KIAA2026 | c.2061G>T p.K687N | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67355853; called by muse, mutect2, varscan2
- KRT38 | c.713T>A p.L238H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55846392; called by muse, mutect2, varscan2
- L3MBTL3 | c.778A>T p.N260Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV62386719; called by muse, mutect2, varscan2
- LAMA5 | c.6577C>G p.R2193G | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.109); catalogued as COSV53362441; called by muse, mutect2, varscan2
- LRRIQ1 | c.4162A>G p.I1388V | Missense Mutation (SNP) | VAF 130/271 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs1283825943, COSV67832599; called by muse, mutect2, varscan2
- LRTM2 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs777755623, COSV54565460; called by muse, mutect2, varscan2
- MAP1B | c.4139T>A p.M1380K | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.942); catalogued as COSV57100816; called by muse, mutect2, varscan2
- MGA | c.7274G>A p.R2425H (on ENST00000219905 / NM_001164273.1; = p.R2216H on NM_001080541.2) | Missense Mutation (SNP) | VAF 73/115 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54956331; called by muse, mutect2, varscan2
- MME | c.1163A>T p.K388M | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64708121; called by muse, mutect2, varscan2
- MMP15 | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147717123; called by muse, mutect2, varscan2
- MPHOSPH10 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV54906236; called by muse, mutect2, varscan2
- NLGN3 | c.1192A>C p.N398H (on ENST00000358741 / NM_181303.2; = p.N378H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62444056; called by muse, mutect2, varscan2
- NLRP9 | c.2746A>T p.R916W | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV60464375; called by muse, mutect2, varscan2
- NOX1 | c.1301A>G p.Y434C | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54195064; called by muse, mutect2, varscan2
- NOX3 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 48/68 reads (71%) | catalogued as COSV50154515; called by muse, mutect2, varscan2
- NXPE3 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1469234935, COSV56290391; called by muse, mutect2, varscan2
- OR10H4 | c.37A>T p.N13Y | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV59062194; called by muse, mutect2, varscan2
- OR5I1 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56887030; called by muse, varscan2
- OR5I1 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV100041408; called by muse, varscan2
- PCDHA13 | c.496T>A p.S166T | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV56514299; called by muse, mutect2, varscan2
- PCDHB4 | c.1187T>C p.L396S | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV52023623; called by muse, varscan2
- PCDHGA10 | c.2117G>T p.C706F | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs778092218, COSV53967951; called by muse, mutect2, varscan2
- PDE1C | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs964367849, COSV100372251, COSV58513919; called by muse, mutect2, varscan2
- PHF7 | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV56235728; called by muse, mutect2, varscan2
- PLEKHA5 | c.1699T>C p.S567P | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.894); catalogued as rs752239578, COSV54703249; called by muse, mutect2, varscan2
- POPDC3 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs758687042, COSV54644603; called by muse, mutect2, varscan2
- RAB33A | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV57062233, COSV57063641; called by muse, mutect2, varscan2
- RNASE1 | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61754064; called by muse, mutect2, varscan2
- RPS6KA3 | c.1765-2A>T p.X589_splice | Splice Site (SNP) | VAF 103/204 reads (50%) | catalogued as COSV65388243; called by muse, mutect2, varscan2
- SCN9A | c.1099T>A p.Y367N | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57613431; called by muse, mutect2, varscan2
- SLITRK6 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV68390451; called by muse, mutect2, varscan2
- SMARCA4 | c.2731G>A p.G911S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758185, COSV60798378; called by muse, mutect2, varscan2
- SUOX | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776955991, COSV56269343; called by muse, mutect2, varscan2
- SVIL | c.3010G>A p.A1004T (on ENST00000355867 / NM_021738.3; = p.A578T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as rs374116755; called by muse, mutect2, varscan2
- TFE3 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV59947567; called by muse, mutect2, varscan2
- TOP2B | c.3763A>G p.K1255E (on ENST00000264331 / NM_001330700.2; = p.K1250E on NM_001068.3) | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.113); catalogued as COSV51973351; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62626307; called by muse, mutect2, varscan2
- TRIO | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated (0.52); PolyPhen benign (0.163); catalogued as rs1383482299, COSV60085900; called by muse, mutect2, varscan2
- TRIP12 | c.3898A>T p.R1300* | Nonsense Mutation (SNP) | VAF 38/63 reads (60%) | catalogued as COSV104369762, COSV52266311; called by muse, mutect2, varscan2
- TRMT10B | c.86A>C p.E29A | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1420209068, COSV53050563; called by muse, mutect2, varscan2
- USP34 | c.9385-2A>C p.X3129_splice | Splice Site (SNP) | VAF 32/51 reads (63%) | catalogued as COSV68402462, COSV68406747; called by muse, mutect2, varscan2
- VIM | c.1270A>T p.R424W | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56406261; called by muse, mutect2, varscan2
- ZNF30 | c.1480A>G p.S494G | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs769672268, COSV57854259; called by muse, mutect2, varscan2
- ZNF595 | c.1351C>A p.P451T | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100227664; called by muse, mutect2, varscan2
- RORB | c.1193_1195del p.K398del (on ENST00000396204 / NM_001365023.1; = p.K387del on NM_006914.4) | In Frame Del (DEL) | VAF 110/264 reads (42%) | called by mutect2, pindel, varscan2
- SUPT16H | c.2105_2110delinsTGC p.N702_I704delinsML | In Frame Del (DEL) | VAF 73/228 reads (32%) | called by pindel, varscan2*
- ZBTB14 | c.1297del p.A433Qfs*14 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.1359A>C p.P453= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV50756550; called by muse, mutect2, varscan2
- APOB | c.2109T>C p.A703= | Silent (SNP) | VAF 75/144 reads (52%) | catalogued as COSV51939919; called by muse, mutect2, varscan2
- CAMKMT | c.771G>T p.A257= | Silent (SNP) | VAF 52/94 reads (55%) | catalogued as COSV65926498; called by muse, mutect2, varscan2
- CDC37 | c.219G>A p.V73= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV55768741; called by muse, mutect2, varscan2
- CDHR3 | c.2004T>C p.V668= | Silent (SNP) | VAF 82/179 reads (46%) | catalogued as COSV58418406; called by muse, mutect2, varscan2
- DNAH1 | c.7761G>T p.V2587= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV101325719; called by muse, mutect2, varscan2
- KCNU1 | c.2880G>T p.R960= | Silent (SNP) | VAF 60/141 reads (43%) | catalogued as rs769435361, COSV67757076; called by muse, mutect2, varscan2
- KLHL2 | c.1620A>G p.A540= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV56976232; called by muse, mutect2, varscan2
- NBEA | c.5727C>T p.F1909= | Silent (SNP) | VAF 65/141 reads (46%) | catalogued as COSV59794004; called by muse, mutect2, varscan2
- OR10R2 | c.150T>A p.V50= | Silent (SNP) | VAF 59/140 reads (42%) | catalogued as COSV63768981; called by muse, varscan2
- SCGB2A2 | c.75G>A p.L25= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV57174704; called by muse, mutect2, varscan2
- DBN1 | c.86+1260T>C | Intron (SNP) | VAF 46/98 reads (47%) | catalogued as COSV52790239; called by muse, mutect2, varscan2
- TPM2 | chr9:35682079 C>T | 3'Flank (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100253231, COSV100253621; called by mutect2, varscan2
